Surgical pathology report (de-identified scan), TCGA case TCGA-FB-AAPY, project TCGA-PAAD (Pancreatic Adenocarcinoma), tissue source site Asterand, specimen TCGA-FB-AAPY-01A (Primary Tumor).

[page 1 of 2]
TSS Patient ID:

Surgical Date:

Gross Description: Pancreas and duodenum, pancreaticoduodenectomy:

- Pancreatic ductal adenocarcinoma, moderately differentiated, 3.5 cm in greatest dimension, limited to pancreas (see worksheet)

- Perineural invasion identified

- Resection margins negative for malignancy

- Metastatic carcinoma in two of nine lymph nodes (2/9)

ICD-O-3

Adenocarcinoma, duct NOS
Site: Pancreas head 8500/3
025.0
J40 5/16/14

Microscopic Description:

Diagnosis Details:

Comments: Tumor Site (check all that apply): Pancreatic head

Tumor Size: Tumor size greatest dimension: 3.5cm

Histologic Type: Ductal adenocarcinoma

Histologic Grade: G2: Moderately differentiated

AJCC Stage (pTNM)

Primary Tumor (pT): pT2

Regional Lymph Nodes (pN): N1b

Number of regional lymph nodes involved: 2

Number of regional lymph nodes examined: 9

Distant Metastasis (pM): pMX

Margin(s) negative for invasive carcinoma

Angiolymphatic Invasion (V/L): Absent

Perineural Invasion: Present

Formatted Path Reports: PANCREAS TISSUE CHECKLIST

Specimen type: Whipple resection

Tumor site: Head

[page 2 of 2]
Tumor size: 3.5 cm

Histologic type: Adenocarcinoma, ductal type

Histologic grade: Moderately differentiated

Tumor extent: Not specified

Lymph nodes: 2/9 positive for metastasis (Regional 2/9)

Lymphatic invasion: Absent

Venous invasion: Absent

Margins: Uninvolved

Evidence of neo-adjuvant treatment: Not specified

Additional pathologic findings: Not specified

Comments: None

Source: NCI Genomic Data Commons file 6339bb40-5446-4ae3-9f06-567d056f3cac (TCGA-FB-AAPY.BE077658-3286-455B-A84E-87CEA81BEF59.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).